Somatic mutation profile of tumor specimen TCGA-N8-A4PO-01A (aliquot TCGA-N8-A4PO-01A-11D-A28R-08) from TCGA case TCGA-N8-A4PO, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Isthmus uteri; FIGO stage: Stage II; Age at diagnosis: 66.0 years (24,124 days).
Specimen TCGA-N8-A4PO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11dd633b-31b2-4cf5-b57f-06622e6314b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N8-A4PO-10A (Blood Derived Normal), aliquot TCGA-N8-A4PO-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1703484c-f579-4929-8d73-145a53c817cc

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Nonsense Mutation 4, RNA 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 53/61 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs764681188, COSV55610207; called by muse, mutect2, varscan2
- CPA6 | c.652A>C p.K218Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52720603; called by muse, mutect2
- FAAP100 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs761492226, COSV59888045; called by muse, mutect2, varscan2
- JAK3 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs376945173; called by muse, mutect2, varscan2
- KDM1B | c.2187G>C p.Q729H (on ENST00000449850; = p.Q496H on NM_153042.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1319318846; called by muse, mutect2, varscan2
- KIFC1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.66); catalogued as rs146314962; called by muse, mutect2
- KIR3DL1 | c.614A>T p.Q205L | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1396537950; called by muse, mutect2, varscan2
- KMT2D | c.3926C>T p.P1309L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs868758414; called by muse, mutect2, varscan2
- MEIS2 | c.163G>A p.A55T (on ENST00000561208 / NM_170675.5; = p.A42T on NM_002399.3) | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs773159665; called by muse, mutect2, varscan2
- MMP25 | c.813C>G p.D271E | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1361734416; called by muse, mutect2
- PRR23B | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1172972381; called by muse, mutect2
- PTP4A3 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs945482557, COSV61472756; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54576481; called by muse, mutect2, varscan2
- RAPGEF3 | c.2402G>A p.R801Q (on ENST00000389212; = p.R759Q on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796826496; called by muse, mutect2, varscan2
- RHCG | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs769791679; called by mutect2, varscan2
- RNF214 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375077963; called by muse, mutect2, varscan2
- RYR2 | c.9655G>A p.V3219M | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as rs371147744, CM1411479; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- SLC27A6 | c.1377C>G p.Y459* | Nonsense Mutation (SNP) | VAF 22/87 reads (25%) | catalogued as rs772208898; called by muse, mutect2, varscan2
- TBK1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs56196591, CM1513127, COSV59155738; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP50 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 24/30 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV101597745; called by muse, mutect2, varscan2
- ALK | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ARHGEF2 | c.2647C>T p.R883W (on ENST00000361247 / NM_001162383.2; = p.R855W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARMC1 | c.377C>A p.S126* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- ATP13A4 | c.832C>A p.R278S | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- C2orf16 | c.3641C>T p.T1214I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CCNE2 | c.505T>A p.F169I | Missense Mutation (SNP) | VAF 60/83 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- CHD5 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- DNAH9 | c.6581T>A p.I2194N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAJB12 | c.1091G>A p.W364* (on ENST00000338820; = p.W330* on NM_017626.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- DNM2 | c.1291G>C p.V431L | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EEPD1 | c.125T>G p.I42S | Missense Mutation (SNP) | VAF 90/158 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- FUT3 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GPR182 | c.640T>C p.W214R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCRTR2 | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA10 | c.2818C>T p.H940Y | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- KCNMA1 | c.2566G>T p.G856C (on ENST00000286628 / NM_001161352.2; = p.G798C on NM_002247.4) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K4 | c.4174A>C p.K1392Q | Missense Mutation (SNP) | VAF 88/173 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- MROH2B | c.4700C>G p.A1567G | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NR3C2 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NR4A3 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 48/54 reads (89%) | called by muse, mutect2, varscan2
- PRDM15 | c.1870C>T p.H624Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAV1 | c.230C>G p.P77R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SFTPB | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2
- SLC10A5 | c.603G>C p.L201F | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMC2 | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (0.09); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- SYT17 | c.684C>A p.N228K | Missense Mutation (SNP) | VAF 35/369 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- THEMIS2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMEM132B | c.2666T>C p.V889A | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.085); called by muse, mutect2
- TRIM14 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRIO | c.6867C>G p.N2289K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.175); called by muse, mutect2
- ULBP2 | c.485A>C p.H162P | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); called by muse, varscan2
- ZSWIM7 | c.202-2A>T p.X68_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- CACNA1G | c.5445T>C p.C1815= | Silent (SNP) | VAF 14/72 reads (19%) | called by mutect2, varscan2
- CHAD | c.369C>T p.T123= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1407454955; called by muse, mutect2
- COG6 | c.1605A>C p.T535= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- CYP2F1 | c.108C>A p.P36= | Silent (SNP) | VAF 108/365 reads (30%) | called by muse, mutect2, varscan2
- FBLN2 | c.474G>T p.R158= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- FCHSD2 | c.1977C>T p.Y659= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as rs1343866344; called by muse, mutect2, varscan2
- HSPA5 | c.288G>A p.K96= | Silent (SNP) | VAF 37/104 reads (36%) | called by muse, mutect2, varscan2
- NCAPG2 | c.1311T>C p.R437= | Silent (SNP) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- PCMTD1 | c.261G>T p.L87= | Silent (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- SLC18A2 | c.1152C>A p.L384= | Silent (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- TRPM6 | c.2088G>C p.T696= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV62515342, COSV62516403; called by muse, mutect2, varscan2
- ZAN | c.3363C>T p.P1121= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs773624759, COSV100769777; called by muse, mutect2, varscan2
- C3P1 | n.2536T>C | RNA (SNP) | VAF 35/165 reads (21%) | called by muse, mutect2, varscan2
- DENND10P1 | n.278G>T | RNA (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
